Gene-level copy-number profile of tumor specimen TCGA-YU-A94C-01A from TCGA case TCGA-YU-A94C, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 24.0 years (8,769 days).
Specimen TCGA-YU-A94C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ecac306-8781-4d02-a700-fcb7fdb7d7da.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-YU-A94C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/cd43110b-6fac-456d-bc5c-ceb8f43fb826

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 2,323; copy number 2: 24,791; copy number 3: 27,915; copy number 4: 2,617; copy number 5: 398; copy number 8: 23; copy number 9: 783; copy number 10: 25.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:39,734,670–40,106,661, 9 genes (within-gene range 0–2): RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1.
- chr9:39,983,821–39,984,401, 1 gene: RPL7AP49.
- chr9:41,979,352–42,189,887, 3 genes: CR788268.1, RN7SL343P, SPATA31A6.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:58,106,423–58,267,894, 3 genes: AC026884.1, IPMK, TPT1P10.
- chr10:87,201,647–87,357,882, 5 genes (within-gene range 0–1): NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 831 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–34,249,958, 831 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,811. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
